Somatic mutation profile of tumor specimen TCGA-W5-AA2Z-01A (aliquot TCGA-W5-AA2Z-01A-11D-A417-09) from TCGA case TCGA-W5-AA2Z, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 29.2 years (10,659 days).
Specimen TCGA-W5-AA2Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60cafd89-242d-4328-8a8e-a26c84cc53d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA2Z-11A (Solid Tissue Normal), aliquot TCGA-W5-AA2Z-11A-11D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74833419-250c-4500-a4fd-8e7d4353ff6c

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Nonsense Mutation 3, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP36 | c.688C>G p.P230A | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52268230; called by muse, mutect2
- CALCR | c.1259G>A p.R420H (on ENST00000649521 / NM_001164737.2; = p.R404H on NM_001742.4) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64008678; called by muse, mutect2, varscan2
- DTX1 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs764389287; called by muse, mutect2, varscan2
- DYRK4 | c.118+1G>A p.X40_splice | Splice Site (SNP) | VAF 22/66 reads (33%) | catalogued as rs1363325745; called by muse, mutect2, varscan2
- MUC5B | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs754603108; called by muse, mutect2, varscan2
- NRG2 | c.519dup p.L174Afs*35 | Frame Shift Ins (INS) | VAF 8/47 reads (17%) | catalogued as rs765864415; called by mutect2, pindel, varscan2
- ZNF598 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs560217707; called by muse, varscan2
- AFF4 | c.1621G>T p.E541* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- BICD1 | c.1210C>T p.H404Y | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.137); called by muse, mutect2
- BRD7 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | called by muse, varscan2
- BTN3A1 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.393); called by muse, mutect2
- FOXK1 | c.514G>T p.G172W | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGSF10 | c.4758del p.G1587Afs*6 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- MGME1 | c.630G>C p.Q210H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- MYO7A | c.1888C>A p.P630T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPRD2 | c.3826C>T p.P1276S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCN3B | c.359G>C p.C120S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SELL | c.1118A>G p.K373R (on ENST00000650983; = p.K360R on NM_000655.5) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, varscan2
- SELL | c.1042T>C p.F348L (on ENST00000650983; = p.F335L on NM_000655.5) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, varscan2
- SLC9C1 | c.1298C>G p.S433* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- TEDC2 | c.211C>G p.P71A | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- TIGD3 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CACNA1E | c.1353G>A p.K451= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs1041984686; called by muse, mutect2
- IVL | c.753G>A p.G251= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs45544033; called by mutect2, varscan2
- PSG8 | c.522G>A p.P174= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as rs187064013; called by muse, mutect2, varscan2
- SLCO4C1 | c.1791T>C p.P597= | Silent (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- SLX4 | c.2799C>A p.G933= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- ZNF99 | c.*95G>T | 3'UTR (SNP) | VAF 20/45 reads (44%) | catalogued as COSV101233876; called by muse, mutect2, varscan2
